Somatic mutation profile of tumor specimen TCGA-ZG-A9N3-01A (aliquot TCGA-ZG-A9N3-01A-11D-A41K-08) from TCGA case TCGA-ZG-A9N3, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 73.7 years (26,902 days).
Specimen TCGA-ZG-A9N3-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7b5b8f12-24a7-427b-a080-8bde2b3e169f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-ZG-A9N3-10A (Blood Derived Normal), aliquot TCGA-ZG-A9N3-10A-01D-A41N-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c9de64c8-32d7-4781-9ef1-809f7e114faf

The open-access MAF lists 57 somatic variants for this specimen: 39 protein-altering or splice-affecting, 18 silent.
By variant classification: Missense Mutation 34, Silent 18, In Frame Del 2, Splice Region 1, Frame Shift Del 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AHNAK | c.12891A>T p.K4297N | Missense Mutation (SNP) | VAF 121/359 reads (34%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.672); catalogued as COSV99947654; called by muse, mutect2, varscan2
- BNC2 | c.1851G>T p.M617I | Missense Mutation (SNP) | VAF 11/63 reads (17%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as COSV101033328; called by muse, mutect2, varscan2
- C20orf194 | c.2617C>T p.L873F | Missense Mutation (SNP) | VAF 12/134 reads (9%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.967); catalogued as COSV52691208, COSV99330791; called by muse, mutect2
- CCT8L2 | c.677G>A p.G226E | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.102); catalogued as rs751923445, COSV100742779; called by muse, mutect2, varscan2
- CNDP1 | c.1154C>T p.A385V | Missense Mutation (SNP) | VAF 41/117 reads (35%) | SIFT tolerated (0.82); PolyPhen benign (0); catalogued as rs536184259, COSV62594906; called by muse, mutect2, varscan2
- CTNNA3 | c.1019A>T p.Q340L | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV101049559; called by muse, mutect2, varscan2
- DISP3 | c.3819C>T p.D1273= | Splice Region (SNP) | VAF 9/21 reads (43%) | catalogued as rs777818834, COSV53831013; called by muse, mutect2, varscan2
- DNAH3 | c.8576T>C p.I2859T | Missense Mutation (SNP) | VAF 42/142 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99767710; called by muse, mutect2, varscan2
- ENPP1 | c.2600G>T p.S867I | Missense Mutation (SNP) | VAF 7/120 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV100719547; called by muse, mutect2
- HEATR1 | c.2444C>T p.P815L | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.981); catalogued as COSV100857647; called by muse, mutect2, varscan2
- HNRNPH1 | c.87G>T p.R29S | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT tolerated (0.63); PolyPhen benign (0.145); catalogued as COSV100270654; called by muse, mutect2
- HRG | c.1448C>T p.P483L | Missense Mutation (SNP) | VAF 37/100 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.123); catalogued as rs775005977, COSV51648513; called by muse, mutect2, varscan2
- HSPA8 | c.1460A>G p.N487S | Missense Mutation (SNP) | VAF 21/171 reads (12%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.145); catalogued as rs749707173, COSV57084610; called by muse, mutect2, varscan2
- IGFBP3 | c.419C>T p.S140L | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.217); catalogued as rs139238956, COSV51872336; called by muse, mutect2, varscan2
- ITK | c.295C>T p.R99W | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV70060465; called by muse, mutect2, varscan2
- KIAA2026 | c.4655C>T p.P1552L | Missense Mutation (SNP) | VAF 65/169 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs774362474, COSV101199066; called by muse, mutect2, varscan2
- KLHL26 | c.86C>T p.T29M | Missense Mutation (SNP) | VAF 25/154 reads (16%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as rs528604281, COSV99963187; called by muse, mutect2
- KRT37 | c.649G>A p.A217T | Missense Mutation (SNP) | VAF 25/49 reads (51%) | SIFT deleterious (0); PolyPhen benign (0.007); catalogued as rs149307038; called by muse, mutect2, varscan2
- METTL25 | c.415del p.Q139Rfs*13 | Frame Shift Del (DEL) | VAF 15/111 reads (14%) | catalogued as COSV99942585; called by mutect2, pindel, varscan2
- MUC5B | c.13777G>A p.V4593M | Missense Mutation (SNP) | VAF 14/108 reads (13%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.432); catalogued as COSV101500379; called by muse, mutect2, varscan2
- MYRIP | c.1513A>G p.R505G | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as COSV100219271; called by muse, mutect2, varscan2
- NR1D1 | c.1837G>A p.A613T | Missense Mutation (SNP) | VAF 12/86 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.312); catalogued as COSV99225527; called by muse, mutect2, varscan2
- OR52L1 | c.540G>T p.L180F | Missense Mutation (SNP) | VAF 14/88 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100176180; called by muse, mutect2, varscan2
- PCDH10 | c.2830T>A p.C944S | Missense Mutation (SNP) | VAF 12/78 reads (15%) | SIFT tolerated (0.36); PolyPhen probably damaging (0.977); catalogued as COSV99993643; called by muse, mutect2, varscan2
- RPL7 | c.562G>C p.E188Q | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); catalogued as COSV99536323, COSV99536432; called by muse, mutect2, varscan2
- SHANK3 | c.1937G>A p.G646D | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV99437025; called by muse, mutect2, varscan2
- SPATA31D1 | c.2282C>T p.S761L | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.125); catalogued as COSV100782794; called by muse, mutect2, varscan2
- SSTR4 | c.458G>A p.R153H | Missense Mutation (SNP) | VAF 14/113 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.427); catalogued as rs542657849, COSV54796687, COSV99658529; called by muse, mutect2, varscan2
- SYNE1 | c.9836T>A p.V3279D (on ENST00000367255 / NM_182961.4; = p.V3286D on NM_033071.3) | Missense Mutation (SNP) | VAF 24/113 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.83); catalogued as COSV99565464; called by muse, mutect2, varscan2
- TRIM33 | c.713G>A p.C238Y | Missense Mutation (SNP) | VAF 31/111 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100635392; called by muse, mutect2, varscan2
- TRIM51 | c.1339T>A p.F447I | Missense Mutation (SNP) | VAF 23/131 reads (18%) | SIFT tolerated (0.3); PolyPhen benign (0.026); catalogued as COSV99792639; called by muse, mutect2, varscan2
- UBE2C | c.317A>G p.N106S | Missense Mutation (SNP) | VAF 21/119 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.119); catalogued as rs770704295, COSV99708620; called by muse, mutect2, varscan2
- UFL1 | c.2054T>C p.I685T | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV100990074; called by muse, mutect2, varscan2
- USP29 | c.2312C>A p.S771Y | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.042); catalogued as COSV99518132; called by muse, mutect2
- VGLL2 | c.61G>A p.A21T | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.578); catalogued as COSV100409926, COSV58310699; called by muse, mutect2, varscan2
- XIRP2 | c.3997G>T p.G1333C (on ENST00000628543; = p.G1508C on NM_152381.6) | Missense Mutation (SNP) | VAF 25/73 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.315); catalogued as rs1337434645, COSV99743245; called by muse, mutect2, varscan2
- ATM | c.3106_3114del p.F1036_V1038del | In Frame Del (DEL) | VAF 49/109 reads (45%) | called by mutect2, pindel, varscan2
- LRRK1 | c.1288_1290del p.C430del | In Frame Del (DEL) | VAF 13/77 reads (17%) | called by pindel, varscan2
- SUPT20HL2 | c.1092T>A p.C364* | Nonsense Mutation (SNP) | VAF 6/40 reads (15%) | called by muse, mutect2, varscan2
- ANP32A | c.141A>G p.L47= | Silent (SNP) | VAF 38/106 reads (36%) | catalogued as rs1242160916, COSV99143033; called by muse, mutect2, varscan2
- APBB1IP | c.1035A>G p.G345= | Silent (SNP) | VAF 30/175 reads (17%) | catalogued as COSV100882058; called by muse, mutect2, varscan2
- ASIC1 | c.867C>A p.T289= | Silent (SNP) | VAF 14/68 reads (21%) | catalogued as COSV99948086; called by muse, varscan2
- BTN3A3 | c.1203G>C p.V401= | Silent (SNP) | VAF 5/44 reads (11%) | catalogued as COSV99764899; called by muse, mutect2, varscan2
- CD1C | c.336T>C p.F112= | Silent (SNP) | VAF 44/110 reads (40%) | catalogued as COSV100939393; called by muse, mutect2, varscan2
- CENPT | c.691C>T p.L231= | Silent (SNP) | VAF 5/35 reads (14%) | catalogued as COSV99535119; called by mutect2, varscan2
- FAT3 | c.810T>C p.T270= | Silent (SNP) | VAF 15/102 reads (15%) | catalogued as COSV53119895, COSV99966498; called by muse, mutect2, varscan2
- GON4L | c.3723C>G p.A1241= | Silent (SNP) | VAF 14/77 reads (18%) | catalogued as COSV99674380; called by muse, mutect2, varscan2
- GRIN2A | c.2889C>T p.L963= | Silent (SNP) | VAF 29/143 reads (20%) | catalogued as COSV100409935; called by muse, mutect2, varscan2
- HYOU1 | c.2028C>T p.G676= | Silent (SNP) | VAF 26/81 reads (32%) | catalogued as rs375091924, COSV68215632; ClinVar: likely benign; called by muse, mutect2, varscan2
- ITPKC | c.657T>C p.A219= | Silent (SNP) | VAF 3/26 reads (12%) | catalogued as COSV99648769; called by muse, mutect2
- KCNJ16 | c.12C>T p.Y4= | Silent (SNP) | VAF 9/47 reads (19%) | catalogued as rs377652819; called by muse, mutect2, varscan2
- RELB | c.630G>A p.V210= | Silent (SNP) | VAF 17/52 reads (33%) | catalogued as rs1192786296, COSV99672933; called by muse, mutect2, varscan2
- SIGLEC8 | c.1314G>A p.S438= | Silent (SNP) | VAF 18/49 reads (37%) | catalogued as rs200706657, COSV58474223; called by muse, mutect2, varscan2
- SP2 | c.108C>G p.A36= | Silent (SNP) | VAF 52/240 reads (22%) | catalogued as COSV100947196; called by muse, mutect2, varscan2
- TBC1D7 | c.501G>T p.R167= | Silent (SNP) | VAF 47/143 reads (33%) | catalogued as COSV100568614; called by muse, mutect2, varscan2
- TRDN | c.1305G>A p.A435= | Silent (SNP) | VAF 5/13 reads (38%) | catalogued as rs1170118704, COSV62114484; ClinVar: likely benign; called by muse, mutect2, varscan2
- VIPR1 | c.582C>A p.I194= | Silent (SNP) | VAF 4/64 reads (6%) | catalogued as COSV100285637; called by muse, mutect2
